Somatic mutation profile of tumor specimen MP2PRT-PAVVCA-TBP1-A (aliquot MP2PRT-PAVVCA-TBP1-A-1-0-D-A82B-36) from MP2PRT case MP2PRT-PAVVCA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,158 days).
Specimen MP2PRT-PAVVCA-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea44175b-e6ed-4d5b-9d47-e14269a2537a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVVCA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVVCA-NB1-A-1-0-D-A82B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7e24192-8af6-47ca-b854-d9544b63d0d1

The open-access MAF lists 23 somatic variants for this specimen: 14 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 8, 5'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4337G>A p.R1446H | Missense Mutation (SNP) | VAF 117/378 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519884, COSV52112787, COSV52125401, COSV52132241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 74/477 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 50/548 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- CADM1 | c.971C>T p.S324L | Missense Mutation (SNP) | VAF 60/231 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.153); catalogued as rs376941564; called by muse, varscan2
- CILP2 | c.2165G>A p.R722Q | Missense Mutation (SNP) | VAF 238/730 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.295); catalogued as rs1220091234; called by muse, mutect2, varscan2
- CSMD2 | c.7961G>A p.R2654Q | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1000408473, COSV53942325, COSV53971497; called by muse, mutect2
- DISP2 | c.2501C>T p.T834M | Missense Mutation (SNP) | VAF 225/727 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV51121036; called by muse, mutect2, varscan2
- FAM3A | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 21/748 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV59194200; called by muse, mutect2
- IGLV3-12 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 33/520 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.102); catalogued as rs575874345; called by muse, mutect2
- RASGEF1B | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 26/526 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1218124640; called by muse, mutect2
- IGLV4-69 | c.358dup p.*120P | In Frame Ins (INS) | VAF 49/108 reads (45%) | called by mutect2, varscan2
- NLRC4 | c.2154G>T p.M718I | Missense Mutation (SNP) | VAF 34/382 reads (9%) | SIFT tolerated (0.95); PolyPhen benign (0); called by muse, mutect2
- TMEM132C | c.2227G>C p.A743P | Missense Mutation (SNP) | VAF 14/530 reads (3%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.735); called by muse, mutect2
- TMEM229B | c.361G>C p.A121P | Missense Mutation (SNP) | VAF 50/960 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2
- BCL11B | c.1254G>A p.P418= (on ENST00000357195 / NM_001282237.2; = p.P347= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 215/1001 reads (21%) | catalogued as rs370633683; called by muse, mutect2, varscan2
- CXCR3 | c.945G>A p.P315= | Silent (SNP) | VAF 60/1338 reads (4%) | catalogued as COSV65462022; called by muse, mutect2
- FAM47A | c.168C>T p.D56= | Silent (SNP) | VAF 141/729 reads (19%) | catalogued as rs200832901, COSV60497226; called by muse, mutect2, varscan2
- IGLV4-69 | c.359delinsCC p.*120P | Silent (INS) | VAF 56/176 reads (32%) | called by mutect2*, pindel, varscan2*
- SCGB1D2 | c.63C>T p.A21= | Silent (SNP) | VAF 70/274 reads (26%) | catalogued as rs754124729; called by muse, mutect2
- SFT2D1 | c.177C>T p.G59= | Silent (SNP) | VAF 20/452 reads (4%) | catalogued as rs1327222564, COSV100674908; called by muse, mutect2
- WDR4 | c.822C>T p.D274= | Silent (SNP) | VAF 73/721 reads (10%) | catalogued as rs772529334, COSV100375011; called by muse, mutect2, varscan2
- WNT3A | c.246C>T p.R82= | Silent (SNP) | VAF 50/612 reads (8%) | catalogued as rs764558716, COSV52733989; called by muse, mutect2
- DCLK3 | c.-84C>T | 5'UTR (SNP) | VAF 26/440 reads (6%) | catalogued as rs775665920; called by muse, mutect2
